Somatic mutation profile of tumor specimen TCGA-G6-A5PC-01A (aliquot TCGA-G6-A5PC-01A-11D-A33K-10) from TCGA case TCGA-G6-A5PC, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 54.8 years (20,029 days).
Specimen TCGA-G6-A5PC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0d844eb-699e-4a26-8c1a-c83958193ae5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G6-A5PC-10A (Blood Derived Normal), aliquot TCGA-G6-A5PC-10A-01D-A33K-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eeafa4bf-2eae-4a43-b598-a002e2b0770e

The open-access MAF lists 65 somatic variants for this specimen: 53 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 11, Frame Shift Del 8, Nonsense Mutation 4, Frame Shift Ins 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC4 | c.2841G>C p.W947C | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV100972214; called by muse, mutect2
- AMBN | c.380T>C p.L127P | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.952); catalogued as rs770127979, COSV100534255; called by muse, mutect2, varscan2
- ANKRD13A | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs766253422, COSV55677069; called by muse, mutect2, varscan2
- ARSD | c.961T>G p.L321V | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.364); catalogued as COSV99471932; called by muse, mutect2, varscan2
- ASCC3 | c.4981A>G p.I1661V | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.13); catalogued as rs775959557, COSV100976194; called by muse, mutect2, varscan2
- ASIC2 | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as rs1218719296, COSV63325123; called by muse, mutect2
- CDC42BPB | c.3354T>G p.Y1118* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100775158; called by muse, mutect2
- CDC42BPB | c.3352T>A p.Y1118N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV100775161; called by muse, mutect2
- CDCA2 | c.2479A>G p.R827G | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.73); catalogued as COSV100398732, COSV57947130; called by muse, mutect2, varscan2
- CDH11 | c.1372G>C p.V458L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs776915337, COSV99217087; called by muse, mutect2, varscan2
- COL5A2 | c.2879G>C p.G960A | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66406601; called by muse, mutect2, varscan2
- CRHR1 | c.1194+1G>T p.X398_splice (on ENST00000398285 / NM_001145146.2; = p.X369_splice on NM_004382.5) | Splice Site (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99523262; called by muse, mutect2, varscan2
- DYNC2H1 | c.9263C>G p.P3088R | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100517445; called by muse, mutect2, varscan2
- EZHIP | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1406450484, COSV57956891; called by muse, mutect2, varscan2
- FLACC1 | c.782dup p.M262Dfs*14 | Frame Shift Ins (INS) | VAF 22/56 reads (39%) | catalogued as rs761500161; called by mutect2, varscan2
- GATM | c.139C>G p.R47G | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs749075034, COSV101188100; called by muse, mutect2, varscan2
- GNA14 | c.249G>T p.M83I | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as COSV100502512; called by muse, mutect2, varscan2
- GRM6 | c.2066del p.P689Lfs*24 | Frame Shift Del (DEL) | VAF 43/193 reads (22%) | catalogued as rs755967391, CD119103; called by mutect2, pindel, varscan2
- HEATR5B | c.1919C>G p.P640R | Missense Mutation (SNP) | VAF 98/376 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99248133; called by muse, mutect2, varscan2
- LDLRAD1 | c.414C>A p.D138E | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100997553; called by muse, mutect2, varscan2
- LIN9 | c.916G>T p.D306Y (on ENST00000366808 / NM_001270410.2; = p.D251Y on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100066974; called by muse, mutect2, varscan2
- LTBP2 | c.1225C>A p.R409S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV99999638; called by muse, mutect2, varscan2
- MAST2 | c.2410T>A p.L804M | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV100787814; called by muse, mutect2, varscan2
- NDST4 | c.2291T>C p.L764P | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as rs758551653, COSV99995355; called by muse, mutect2, varscan2
- NRDC | c.3525T>G p.N1175K | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as COSV100542884; called by muse, mutect2, varscan2
- NTHL1 | c.815G>A p.R272K (on ENST00000219066; = p.R264K on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.124); catalogued as COSV99526091; called by mutect2, varscan2
- NTRK2 | c.2050G>A p.V684I (on ENST00000323115 / NM_001369534.1; = p.V700I on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99452181; called by muse, mutect2, varscan2
- NUP205 | c.5296T>G p.S1766A | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99606405; called by muse, mutect2, varscan2
- OIT3 | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763468316, COSV61825463; called by muse, mutect2, varscan2
- OR3A2 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 54/239 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as COSV101375032; called by muse, mutect2, varscan2
- PEX6 | c.2270T>A p.V757E | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99769464; called by muse, mutect2, varscan2
- PIK3R2 | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as rs146112354, COSV99717170; called by muse, mutect2
- PLB1 | c.4022C>T p.T1341I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100577527; called by muse, mutect2, varscan2
- PLEKHA6 | c.2366T>A p.V789E | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as COSV99691484; called by muse, mutect2, varscan2
- RNF103 | c.862T>C p.Y288H | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99409909; called by muse, mutect2, varscan2
- RNF113B | c.808A>T p.K270* | Nonsense Mutation (SNP) | VAF 26/110 reads (24%) | catalogued as COSV99940269; called by muse, mutect2, varscan2
- RPS8 | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV100785462; called by muse, mutect2, varscan2
- RYR3 | c.524G>T p.S175I | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101211942; called by muse, mutect2, varscan2
- SMCO4 | c.5G>A p.R2Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.901); catalogued as rs569882632, COSV100127831, COSV100127938, COSV54360878; called by muse, mutect2, varscan2
- SNX25 | c.1762C>T p.Q588* | Nonsense Mutation (SNP) | VAF 116/427 reads (27%) | catalogued as COSV99252312; called by muse, mutect2, varscan2
- TET2 | c.1975C>T p.Q659* | Nonsense Mutation (SNP) | VAF 15/436 reads (3%) | catalogued as COSV54400844; called by muse, mutect2
- TMEM200C | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101274784; called by mutect2, varscan2
- WNT9A | c.479G>T p.R160L | Missense Mutation (SNP) | VAF 111/284 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.944); catalogued as COSV99688009; called by muse, mutect2, varscan2
- WRAP73 | c.1078G>C p.D360H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99573092; called by muse, mutect2
- ZNF480 | c.1336C>G p.L446V | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); catalogued as COSV100574013; called by muse, mutect2
- BAP1 | c.1853del p.P618Lfs*5 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- CLN8 | c.305_320del p.W102Sfs*20 | Frame Shift Del (DEL) | VAF 20/113 reads (18%) | called by mutect2, varscan2
- CNOT11 | c.518_521del p.F173Yfs*4 | Frame Shift Del (DEL) | VAF 19/90 reads (21%) | called by mutect2, pindel, varscan2
- EXOC6B | c.585del p.D196Mfs*26 | Frame Shift Del (DEL) | VAF 39/167 reads (23%) | called by pindel, varscan2
- KANSL1 | c.1562del p.N521Tfs*57 | Frame Shift Del (DEL) | VAF 19/88 reads (22%) | called by mutect2, pindel, varscan2
- LILRB3 | c.629C>A p.P210H | Missense Mutation (SNP) | VAF 74/408 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TRAPPC11 | c.1852_1855del p.P618Lfs*20 | Frame Shift Del (DEL) | VAF 34/129 reads (26%) | called by mutect2, pindel, varscan2
- USF3 | c.1241del p.L414* | Frame Shift Del (DEL) | VAF 22/104 reads (21%) | called by mutect2, pindel, varscan2
- CAND1 | c.1197T>A p.L399= | Silent (SNP) | VAF 38/143 reads (27%) | catalogued as COSV101598258; called by muse, mutect2, varscan2
- CHRM2 | c.405G>T p.R135= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100280681; called by muse, mutect2, varscan2
- CNDP1 | c.165G>A p.E55= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV100722168; called by muse, mutect2, varscan2
- EPN2 | c.1668G>T p.V556= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV100127325; called by muse, mutect2, varscan2
- HNRNPH1 | c.627T>C p.P209= | Silent (SNP) | VAF 26/141 reads (18%) | catalogued as COSV61486481; called by muse, mutect2, varscan2
- MKRN2 | c.213C>T p.H71= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV99402947; called by muse, mutect2, varscan2
- NIPA2 | c.883T>C p.L295= | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as COSV100487742; called by muse, mutect2, varscan2
- RTTN | c.4569A>G p.L1523= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as COSV99730942; called by muse, mutect2, varscan2
- TAF1 | c.4275C>T p.F1425= (on ENST00000373790 / NM_138923.4; = p.F1446= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/163 reads (17%) | catalogued as COSV99334354; called by muse, mutect2, varscan2
- UBXN2A | c.402A>C p.S134= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV100464768; called by muse, mutect2, varscan2
- ZNF83 | c.432T>G p.T144= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV99991140; called by muse, mutect2, varscan2
- CTSL3P | n.538A>G | RNA (SNP) | VAF 23/92 reads (25%) | called by muse, mutect2
